Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAMR, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAMR-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type: UID:907112FF-1E09-48D1-97BE-01E9BAC0E4D9
*Date - Date of Service: TCGA-XF-AAMR-01A-PR Redacted
Document Status:
Document Title:
Author:
Authenticated By:
Encounter info:
Contributor system:

* Final Report *

INTRAOPERATIVE GROSS CONSULTATION

E: Bladder and prostate:
- all margins are negative

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right distal ureter:
- no tumor identified

BFS: Left distal ureter:
- no tumor identified

CFS: Additional right ureter:
- no tumor identified

DFS: Apical urethral margin:
- no tumor identified

chf *ICD O-3*
path *Carcinoma, urothelial NOS 8120/3*
Carcinoma, transitional cell NOS 8120/3
Site: Bladder, posterior wall C67.4
JW 3/26/14

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "Right distal ureter". It consists of a segment of ureter that measures 0.4 x 0.4 x 0.2 cm. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Left distal ureter". It consists of a 0.4 x 0.4 x 0.2 cm segment of ureter with surrounding fat. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labelled "Additional right ureter F/S". It consists of 1 x 0.5 x 0.5 cm segment of right ureter with surrounding fat. The specimen is entirely submitted for frozen section diagnosis in cassette CFS.

Printed by:
Printed on:

Page 1 of 8
(Continued)

[page 2 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

D: The specimen is received fresh from the O.R. and labelled "Apical urethral margin-F/S". It consists of a 1 x 0.3 x 0.2 cm soft brown-tan tissue fragment. The specimen is entirely submitted for frozen section in cassette DFS.

E: The specimen is received fresh from the O.R. and labelled "Bladder and prostate". It consists of a prostatectomy specimen with an overall measurement of 34 x 13 x 4.2 cm. The peritoneum measures 28 x 16 x 3 cm. The bladder itself measures 9 x 9 x 2 cm. The peritoneum is not involved by tumor. Attached to the bladder is a segment of right ureter that measures 4 cm in length and 2.5 cm in circumference and a left ureter measuring 3 cm in length and 1 cm in circumference. The prostate measures 4.7 x 4 x 3.5 cm. The right seminal vesicle measures 2.5 x 1.5 x 0.5 cm and the left seminal vesicle measures 3.5 x 2 x 1 cm. The outer surface of the specimen is inked black. Opening the specimen anteriorly reveals a prostatic urethra that measures 3.7 cm in length and 3.6 cm in circumference. The verumontanum measures 1 x 1.2 x 0.3 cm. The right posterior bladder mucosa, at the area of the right ureterovesical junction, shows 4 x 4 cm gray-tan ulcerated lesion with necrotic surface. Sectioning of the ulcerated lesion shows a mass that invades through the entire wall thickness of the urinary bladder and extends into the perivesical fat. At the request of the surgeon, an intraoperative pathologic consultation is performed in order to aid in the care of this patient. Representative sections are submitted in 26 cassettes.

F: The specimen is received in formalin and labelled "Left para aortic L.N.". It consists of a 3 x 1.5 x 1 cm soft brown-tan tissue fragment. One lymph node is identified. The specimen is entirely submitted in three cassettes.

G: The specimen is received in formalin and labelled "Right para caval L.N.". It consists of a 3 x 1 x 0.5 cm soft brown-tan fibrofatty tissue fragment. One lymph node that measures up to 0.7 cm in greatest dimension is identified. The specimen is entirely submitted in two cassettes.

H: The specimen is received in formalin and labelled "Right common iliac L.N.". It consists of a 3 x 2 x 1 cm soft brown-tan fibrofatty tissue fragment. Two lymph nodes ranging in size from 0.6 to 2.7 cm are identified. The specimen is entirely submitted in two cassettes.

I: The specimen is received in formalin and labelled "Left common iliac L.N.". It consists of a 2 x 2 x 1 cm aggregate of multiple soft brown-tan fibrofatty tissue fragments. Three lymph nodes are identified ranging in size from 0.2 to 1.2 cm in greatest dimension. The specimen is entirely submitted in three cassettes.

J: The specimen is received in formalin and labelled "Right external iliac L.N.". It consists of a 2 x 2 x 1 cm aggregate of multiple soft yellow-tan fibrofatty tissue fragments. Six lymph nodes are identified ranging in size from 0.2 to 0.8

Printed by:
Printed on:

Page 2 of 8
(Continued)

[page 3 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

cm in greatest diameter. The specimen is entirely submitted in three cassettes.

K: The specimen is received in formalin and labelled "Right L.N. of cloquet". It consists of a 1 x 1 x 0.8 cm soft brown-tan fibrofatty tissue fragment. One lymph node that measures up to 1.3 cm in greatest dimension is identified. The specimen is entirely submitted in one cassette.

L: The specimen is received in formalin and labelled "Right obturator hypogastric L.N.". It consists of a 4 x 3 x 1.5 cm aggregate of multiple soft yellow-tan fibrofatty tissue fragments. The specimen is entirely submitted in five cassettes.

M: The specimen is received in formalin and labelled "Left L.N. of cloquet". It consists of a 1.3 cm lymph node. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labelled "Left external iliac L.N.". It consists of a 2 x 2 x 0.5 cm aggregate of soft yellow-tan fibrofatty tissue fragments. The specimen is entirely submitted in one cassette.

O: The specimen is received in formalin and labelled "Left obturator hypogastric L.N.". It consists of a 5 x 3 x 1 cm soft yellow-tan fibrofatty tissue fragment. The specimen is entirely submitted in five cassettes.

P: The specimen is received in formalin and labelled "Right pre sciatic L.N.". It consists of a 1.5 x 1 x 0.3 cm aggregate of multiple soft brown-tan fibrofatty tissue fragments. Two lymph nodes ranging in size from 0.4 to 0.6 cm are identified. The specimen is entirely submitted in one cassette.

Q: The specimen is received in formalin and labelled "Pre sacral L.N.". It consists of a 4 x 2 x 0.5 cm soft brown-tan fibrofatty tissue fragment. Four lymph nodes are identified ranging in size from 0.3 to 0.6 cm in greatest diameter. The specimen is entirely submitted in four cassettes.

R: The specimen is received in formalin and labelled "Left pre sciatic L.N.". It consists of a 0.5 x 0.5 x 0.2 cm aggregate of multiple soft yellow-tan fibrofatty tissue fragments. The specimen is entirely submitted in one cassette.

S: The specimen is received in formalin and labelled "Left proximal ureter". It consists of a portion of ureter that has three metallic staples. The specimen measures 1.5 x 1 x 0.2 cm. The specimen is serially sectioned and entirely submitted in one cassette.

T: The specimen is received in formalin and labelled "Right proximal ureter". It consists of a portion of ureter. The specimen is entirely submitted in one cassette.

Printed by:
Printed on:

Page 3 of 8
(Continued)

[page 4 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal ureter
CFS: frozen section additional right ureter
DFS: frozen section, apical urethral margin
E1: apex of prostate
E2: right ureter margin
E3: left ureter margin
E4: right ureterovesical junction
E5: left ureterovesical junction
E6: trigone and bladder neck
E7: dome
E8-12: ulcer
E13: ulcer adjacent to right ureter
E14: ulcer
E15: right distal prostate
E16: left distal prostate
E17: right mid prostate
E18: left mid prostate
E19: right proximal prostate
E20: right seminal vesical junction
E21: left proximal prostate
E22: left seminal vesical junction
F1: left para-aortic lymph node; lymph node
F2,3: remaining tissue
G1: right paracaval lymph node; lymph node
G2: remaining tissue
H1: right common iliac lymph node; lymph node
H2: remaining tissue
I1: left common iliac lymph node; lymph node
I2,3: remaining tissue
J1,2: right external iliac lymph node; lymph nodes
J3: remaining tissue
K: right lymph node of cloquet - all embedded
L1: right obturator hypogastric lymph node; two possible lymph nodes
L2-4: one trisected lymph node
L5: remaining tissue
M: left lymph node of cloquet; one lymph node
N: left external iliac lymph node - all embedded
O1: left obturator hypogastric lymph node; three lymph nodes
O2-4: one trisected lymph node
O5: remaining tissue
P: right presciatic lymph node - all embedded
Q1: presacral lymph node; lymph nodes

Printed by:
Printed on:

Page 4 of 8
(Continued)

[page 5 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

Q2-4: remaining tissue
R: left presciatic lymph node - all embedded
S: left proximal ureter- all embedded
T: right proximal ureter - all embedded

Signature Line

CLINICAL INFORMATION:

Pre-Op Dx: Bladder Cancer

Post-Op Dx: Same

SPECIMEN SOURCE:

A: "Right distal ureter"
B: "Left distal ureter"
C: "Additional right ureter F/S"
D: "Apical urethral margin-F/S"
E: "Bladder and prostate"
F: "Left para aortic L.N."
G: "Right para caval L.N."
H: "Right common iliac L.N."
I: "Left common iliac L.N."
J: "Right external iliac L.N."
K: "Right L.N. of cloquet"
L: "Right obturator hypogastric L.N."
M: "Left L.N. of cloquet"
N: "Left external iliac L.N."
O: "Left obturator hypogastric L.N."
P: "Right pre sciatic L.N."
Q: "Pre sacral L.N."
R: "Left pre sciatic L.N."
S: "Left proximal ureter"
T: "Right proximal ureter"

DIAGNOSIS:

RADICAL CYSTECTOMY WITH T-POUCH TO URETHRA:

RIGHT DISTAL URETER (A):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

Printed by:

Printed on:

Page 5 of 8
(Continued)

[page 6 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

ADDITIONAL RIGHT URETER (C):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (D):

INTRAOPERATIVE FROZEN DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL AND PERIURETHRAL TISSUE
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER, PROSTATE AND BILATERAL PERIVESICAL LYMPH NODES (E):

INTRAOPERATIVE GROSS DIAGNOSIS:

- ALL MARGINS ARE NEGATIVE

FINAL DIAGNOSIS:

BLADDER:

- TRANSITIONAL CELL CARCINOMA (4 X 4 CM), GRADE 3/4, INVADING THROUGH MUSCULARIS PROPRIA AND INTO PERIVESICAL SOFT TISSUE
- TUMOR INVOLVES AND OBSTRUCTS THE RIGHT URETEROVESICAL JUNCTION AND EXTENSIVELY INVOLVES RIGHT POSTERIOR BLADDER WALL
- TUMOR DOES NOT INVOLVE THE PROSTATE
- BILATERAL URETER, APEX AND RADIAL MARGINS OF SPECIMEN ARE NEGATIVE FOR TUMOR

PROSTATE:

- PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 6 (3+3), MICROSCOPICALLY INVOLVING RIGHT DISTAL AND MID PROSTATE
- NO CAPSULAR INVOLVEMENT IDENTIFIED
- APICAL AND RADIAL INKED SURGICAL MARGINS ARE NEGATIVE
- BILATERAL SEMINAL VESICLES, NEGATIVE FOR TUMOR
- MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA

Printed by:

Printed on:

Page 6 of 8
(Continued)

[page 7 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

LEFT PARA AORTIC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN 10 LYMPH NODES EXAMINED (0/10)

RIGHT PARACAVAL LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT COMMON ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT COMMON ILIAC LYMPH NODES (I):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT LYMPH NODE OF CLOQUET (K):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

LEFT LYMPH NODE OF CLOQUET (M):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT EXTERNAL ILIAC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN TEN LYMPH NODES EXAMINED (0/10)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT PRESACRAL LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT PRESACRAL LYMPH NODES (R):

- BENIGN FIBROADIPOSE TISSUE
- NO LYMPHOID TISSUE OR MALIGNANCY IDENTIFIED (0/0)

LEFT PROXIMAL URETER (S):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (T):

Printed by:

Printed on:

Page 7 of 8
(Continued)

[page 8 of 8]
SURGICAL PATHOLOGY REPORT

* Final Report *

- HYDROURETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO MALIGNANCY IDENTIFIED IN TOTAL OF 77 LYMPH NODES
EXAMINED (0/77)

PATHOLOGIC TNM STAGE: BLADDER: pT3bN0MX
PROSTATE: pT1aN0MX

Signature Line

Electronically signed by
Verified:

Printed by:
Printed on:

Page 8 of 8
(End of Report)

Source: NCI Genomic Data Commons file f6b44b15-7bce-46a5-ad75-d42196d5a441 (TCGA-XF-AAMR.907112FF-1E09-4BD1-97BE-01E9BAC0E4D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).